Surgical pathology report (de-identified scan), TCGA case TCGA-B7-A5TI, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Cureline, specimen TCGA-B7-A5TI-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/p or container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor call %
					male	Caucasian (White)	Gastric cancer		Stomach, fundus	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Stomach Adenocarcinoma, diffuse	1	4	3	0	none	n/a	70
					male	Caucasian (White)	Gastric cancer		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3

Adenocarcinoma, diffuse type
8/45/3

Site: Gastric fundus c16.1

JW 4/29/13

Source: NCI Genomic Data Commons file cfc453fb-1b75-4d89-a559-edee177bce76 (TCGA-B7-A5TI.DC51A81C-0AF0-46E6-BFE7-8D0D1AA0A54F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).